Somatic mutation profile of tumor specimen ALCH-B1XO-TTP1-A (aliquot ALCH-B1XO-TTP1-A-1-0-D-A772-36) from ALCHEMIST case ALCH-B1XO, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.6 years (22,130 days).
Specimen ALCH-B1XO-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a1e3f97b-e150-4a88-890a-f4edc3395c8b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1XO-NB1-A (Blood Derived Normal), aliquot ALCH-B1XO-NB1-A-1-0-D-A772-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd3efb9c-b94b-4893-b392-2d6aef5124c8

The open-access MAF lists 20 somatic variants for this specimen: 7 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 10, Missense Mutation 7, Intron 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HDAC4 | c.1160T>C p.L387P | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV61860253; called by muse, mutect2
- KLHL11 | c.941A>G p.N314S | Missense Mutation (SNP) | VAF 46/214 reads (21%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs138987988; called by muse, mutect2, varscan2
- GAPVD1 | c.3922G>A p.E1308K (on ENST00000394104; = p.E1317K on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HAS1 | c.1192C>G p.H398D | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); called by muse, mutect2
- LTBP2 | c.4889A>C p.E1630A | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- SPTBN5 | c.10656G>T p.Q3552H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ZFAND2B | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- DYNC1H1 | c.4479C>T p.L1493= | Silent (SNP) | VAF 34/218 reads (16%) | catalogued as rs1213776530, COSV100795144, COSV64140970; called by muse, mutect2, varscan2
- EPDR1 | c.330C>G p.T110= | Silent (SNP) | VAF 45/283 reads (16%) | called by muse, mutect2, varscan2
- HEY1 | c.879C>T p.P293= | Silent (SNP) | VAF 4/26 reads (15%) | called by muse, varscan2
- HNRNPA3 | c.57C>G p.R19= | Silent (SNP) | VAF 3/17 reads (18%) | called by muse, varscan2
- HOXA10 | c.552C>A p.T184= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as rs1188868064; called by muse, mutect2, varscan2
- JPH2 | c.1203G>A p.A401= | Silent (SNP) | VAF 12/186 reads (6%) | catalogued as rs138017620; ClinVar: likely benign; called by muse, mutect2
- KRT82 | c.555G>A p.G185= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as rs1320116787; called by muse, mutect2, varscan2
- LRRC7 | c.2085T>A p.V695= (on ENST00000651989 / NM_001370785.2; = p.V662= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 8/159 reads (5%) | called by muse, mutect2
- PADI6 | c.561G>C p.T187= | Silent (SNP) | VAF 8/160 reads (5%) | catalogued as COSV61883817; called by muse, mutect2
- ZBED5 | c.448C>A p.R150= | Silent (SNP) | VAF 16/272 reads (6%) | catalogued as COSV69721329; called by muse, mutect2
- CPT2 | c.233+47_233+56del | Intron (DEL) | VAF 20/172 reads (12%) | called by mutect2, pindel
- NFKBID | c.-213G>T | 5'UTR (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- TTN | c.10360+5330C>T | Intron (SNP) | VAF 12/102 reads (12%) | called by muse, mutect2
